Somatic mutation profile of tumor specimen C3L-07439-55 (aliquot CPT0409360002) from CPTAC case C3L-07439, project CPTAC-3 (Hematopoietic and reticuloendothelial systems — Myeloid Leukemias). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 24.0 years (8,773 days).
Specimen C3L-07439-55: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 94992410-4d1d-4787-835d-e91e4a9291ef.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-07439-50 (Buccal Cell Normal), aliquot CPT0409330001; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8a65e356-ab19-4a58-9b8b-861c3db386eb

The open-access MAF lists 4 somatic variants for this specimen: 1 protein-altering or splice-affecting, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 5'UTR 1, Intron 1, 5'Flank 1, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 46/164 reads (28%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- MKRN2 | c.-27C>T | 5'UTR (SNP) | VAF 123/254 reads (48%) | catalogued as rs1243117674; called by muse, mutect2, varscan2
- RUFY2 | chr10:68407235 T>C | 5'Flank (SNP) | VAF 3/22 reads (14%) | called by muse, mutect2
- SORBS2 | c.-46+1032C>A | Intron (SNP) | VAF 11/248 reads (4%) | called by muse, mutect2
